Somatic mutation profile of tumor specimen 0DSS5P from CCDI case PBCHYK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.8 years (6,148 days).
Specimen 0DSS5P: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) edfb9d9c-6986-4779-bc22-43c7956d0b42.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSS69 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/07d0eba1-5884-446d-8e66-6625181ad105

The open-access MAF lists 16 somatic variants for this specimen: 11 protein-altering or splice-affecting, 1 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Intron 2, 5'UTR 1, Silent 1, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 65/204 reads (32%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.734G>A p.G245D | Missense Mutation (SNP) | VAF 63/177 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121912656, CM010464, CM900209, COSV52666323, COSV52667838, COSV52745465; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 72/205 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1057519991, COSV52661025, COSV52661712, COSV52690692, COSV52937418; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- DHRS9 | c.944A>G p.N315S | Missense Mutation (SNP) | VAF 42/197 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.024); catalogued as rs1333641035; called by muse, mutect2, varscan2
- LAS1L | c.1372G>A p.A458T | Missense Mutation (SNP) | VAF 52/88 reads (59%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as rs750728472; called by muse, mutect2, varscan2
- LILRA2 | c.33C>T p.L11= | Splice Region (SNP) | VAF 22/338 reads (7%) | catalogued as rs759331053, COSV99252747; called by muse, mutect2
- MED1 | c.1592C>T p.T531I | Missense Mutation (SNP) | VAF 83/226 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56123606; called by muse, mutect2, varscan2
- RFLNB | c.394G>T p.A132S | Missense Mutation (SNP) | VAF 53/164 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV61239201; called by muse, mutect2, varscan2
- SPTAN1 | c.1660C>T p.R554C | Missense Mutation (SNP) | VAF 70/226 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs970895295; called by muse, mutect2, varscan2
- NEB | c.14873C>T p.P4958L | Missense Mutation (SNP) | VAF 92/300 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRPM6 | c.1265A>G p.D422G | Missense Mutation (SNP) | VAF 104/333 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CRBN | c.234T>C p.C78= | Silent (SNP) | VAF 86/295 reads (29%) | called by muse, mutect2, varscan2
- IRAK1 | c.1303-36del | Intron (DEL) | VAF 6/34 reads (18%) | called by mutect2, varscan2
- SLC37A3 | c.1327-35G>C | Intron (SNP) | VAF 78/246 reads (32%) | called by muse, mutect2, varscan2
- ZFP90 | chr16:68539704 del C | 5'Flank (DEL) | VAF 4/16 reads (25%) | called by mutect2, varscan2
- ZYG11B | c.-53G>T | 5'UTR (SNP) | VAF 16/52 reads (31%) | called by mutect2, varscan2
